Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BK-01B (Primary Tumor).

ICD-0-3

Carcinoma, Squamous cell, NOS 8070/3

Site Code: Cervix NOS C53.9 12/24/10

OF SURGIC

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: GYNECOLOGY/OBSTETRICS
Surgeon: [REDACTED]

Pain: [REDACTED]
DOB: [REDACTED]
Sex/Race: [REDACTED]
Location: [REDACTED]
Hosp. No: [REDACTED]
pt./Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, RADICAL HYSTERECTOMY - SQUAMOUS CELL CARCINOMA
MODERATELY DIFFERENTIATED. 2.0 cm IN
GREATEST DIMENSION
- TUMOR INVADDED TO A DEPTH OF 0.6 cm OUT
OF A TOTAL WALL THICKNESS OF 1.2 cm
- FOCAL LYMPHOVASCULAR SPACE INVASION IS
IDENTIFIED (SEE COMMENT)
- DEEP AND VAGINAL RESECTION MARGINS ARE
FREE OF CARCINOMA

UTERUS, PARAMETRIUM, RIGHT AND LEFT, RADICAL HYSTERECTOMY
- NO CARCINOMA IDENTIFIED

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY - SPORADIC ENDOMETRIAL
CYST

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY - ADENOMYOSIS

VAGINA, MARGIN, EXCISION - CHRONIC INFLAMMATION
- FOCAL PARAKERATOSIS
- NO CARCINOMA IDENTIFIED

OVARY, RIGHT, RADICAL HYSTERECTOMY - HYPERTROPHIC CORPUS LUTEUM
CYST
- PARAOVARIAN ADHESIONS

LYMPH NODE, LEFT EXTERNAL (CS1) - NO CARCINOMA IDENTIFIED IN 11
LYMPH NODES (0/11)

LYMPH NODE, LEFT EXTERNAL - NO CARCINOMA IDENTIFIED
- NO LYMPH NODE TISSUE IDENTIFIED
(SPECIMEN ENTIRELY SUBMITTED)

LYMPH NODE, LEFT ORTUTATOR, EXCISION - NO CARCINOMA IDENTIFIED
IN SIX LYMPH NODES (0/6)

LYMPH NODE, LEFT COMMON (CS2), EXCISION - NO CARCINOMA IDENTIFIED
IN ONE LYMPH NODE (0/1)

LYMPH NODE, LEFT COMMON, EXCISION - NO CARCINOMA IDENTIFIED IN 11
LYMPH NODES (0/11)

[REDACTED] M.D.

Source: NCI Genomic Data Commons file 2909bc9b-b9ee-4dd4-9434-63be4758cabb (TCGA-C5-A1BK.E6129BB7-CE4E-400A-B8B9-45DE508C995D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).